Surgical pathology report (de-identified scan), TCGA case TCGA-BR-8295, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-8295-01A (Primary Tumor).

[page 1 of 6]
		Case ID	Gross Description

[page 2 of 6]
Microscopic Description	Diagnosis Details

[page 3 of 6]
Comments	Formatted Path Report
	STOMACH TISSUE CHECKLIST Specimen type: Gastric resection Tumor site: Fundus Tumor size: 5.5 x 5.2 x 1.5 cm Tumor features: None specified Histologic type: Adenocarcinoma, intestinal type Histologic grade: Poorly differentiated Tumor extent: Serosa (visceral peritoneum) Lymph nodes: 0/5 positive for metastasis (Regional 0/5) Lymphatic invasion: Not specified Venous invasion: Not specified Perineural invasion: Not specified Margins: Uninvolved Evidence of neo-adjuvant treatment: Not specified Additional pathologic findings: Not specified Comments: None

[page 4 of 6]
Laterality		ID

[page 5 of 6]
Excision date		Case ID	

Source: NCI Genomic Data Commons file 4afbe126-61ab-4cd4-81ad-82bcccdbe751 (TCGA-BR-8295.F51BE268-2AB3-44E6-ACA3-1142D74461D0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).